Somatic mutation profile of tumor specimen TCGA-EO-A2CH-01A (aliquot TCGA-EO-A2CH-01A-11D-A17W-09) from TCGA case TCGA-EO-A2CH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 73.8 years (26,966 days).
Specimen TCGA-EO-A2CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10254f1-04ad-494a-8214-ceabd1f2f626.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A2CH-10A (Blood Derived Normal), aliquot TCGA-EO-A2CH-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee56a829-2ef4-45f9-a0ba-7ae27b7e7a60

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Frame Shift Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 14/21 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by mutect2, varscan2
- ALG9 | c.1768G>C p.V590L (on ENST00000614444 / NM_001352418.1; = p.V597L on NM_024740.2) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV101211973; called by muse, mutect2, varscan2
- ARID3B | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as rs550927259, COSV60557518; called by muse, mutect2, varscan2
- BCAR3 | c.399A>C p.K133N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV99551405; called by muse, mutect2, varscan2
- CEP104 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs201531250; called by muse, mutect2, varscan2
- CFC1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs773287120, COSV52090573, COSV99383542; called by muse, mutect2, varscan2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CHL1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs752032870, COSV56598659; called by muse, mutect2, varscan2
- CTSE | c.889G>A p.D297N (on ENST00000360218; = p.D292N on NM_001910.4) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs370816867; called by muse, mutect2, varscan2
- CYP46A1 | c.454A>G p.S152G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99952970; called by muse, mutect2, varscan2
- EIF5 | c.1188T>G p.D396E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99385112; called by muse, mutect2, varscan2
- FGD3 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327827982, COSV61597712; called by muse, mutect2, varscan2
- GPR75 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV100766620; called by muse, mutect2, varscan2
- KHDRBS3 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100879134; called by muse, mutect2, varscan2
- LUZP1 | c.582_585del p.S195Rfs*5 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs1346636889; called by mutect2, pindel
- MMP8 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV99368980; called by muse, mutect2, varscan2
- MYH9 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV99340112; called by muse, mutect2
- NDUFAF6 | c.870G>C p.Q290H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV99712960; called by muse, mutect2, varscan2
- NOX3 | c.1137C>A p.S379R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99343777; called by muse, mutect2, varscan2
- NPHP1 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100338605; called by muse, mutect2, varscan2
- NTRK1 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs374799164; called by muse, mutect2, varscan2
- PCNT | c.7483A>T p.I2495F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV64028011; called by muse, mutect2, varscan2
- PIK3R1 | c.1871_1872insA p.W624* (on ENST00000521381 / NM_181523.3; = p.W354* on NM_181504.4) | Nonsense Mutation (INS) | VAF 16/41 reads (39%) | catalogued as COSV99163339; called by mutect2, pindel, varscan2
- SLC24A1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs373003119; called by mutect2, varscan2
- SLC5A5 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs999756094, COSV99715426; called by muse, mutect2, varscan2
- SYCP1 | c.661A>G p.M221V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101051258; called by muse, mutect2, varscan2
- TCEAL6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as rs1264903395, COSV65654349; called by muse, mutect2, varscan2
- TNFAIP3 | c.672C>G p.F224L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.428); catalogued as COSV99397399; called by muse, mutect2, varscan2
- TNPO3 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs940775473, COSV99603721; called by muse, mutect2
- VSTM1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202036784, COSV58074954; called by muse, mutect2
- ZFHX4 | c.3136T>C p.Y1046H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV99269429; called by muse, mutect2, varscan2
- ZFYVE28 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs545040348, COSV99343257; called by muse, mutect2
- ZNF382 | c.1432A>G p.I478V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs758599737, COSV99498216; called by muse, mutect2, varscan2
- ZNF532 | c.2111C>G p.T704S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100267378, COSV60173606; called by muse, mutect2, varscan2
- CCAR2 | c.2124T>G p.A708= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as COSV99374415; called by muse, mutect2, varscan2
- COL4A6 | c.1638G>A p.G546= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100565273; called by muse, mutect2, varscan2
- HRH3 | c.1240C>T p.L414= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as COSV100420773; called by muse, mutect2, varscan2
- IGSF3 | c.1881C>T p.N627= (on ENST00000369486 / NM_001007237.3; = p.N647= on NM_001542.4) | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs374227174; called by muse, mutect2, varscan2
- LAPTM5 | c.594C>T p.V198= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99612736; called by muse, mutect2, varscan2
- MYO1A | c.1878C>T p.A626= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100271059, COSV100271366; called by muse, mutect2, varscan2
- POM121 | c.2739C>T p.S913= (on ENST00000434423; = p.S648= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV99989518; called by muse, mutect2
- POTEM | c.126C>T p.N42= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs746263523, COSV101304811, COSV69155073, COSV69155355; called by muse, mutect2
- SASH1 | c.3069G>A p.R1023= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100821557; called by muse, mutect2, varscan2
- SERPINI2 | c.147C>G p.P49= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV52988911, COSV99248638; called by muse, mutect2, varscan2
- THOP1 | c.2052C>T p.P684= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs766778404, COSV100310862; called by muse, mutect2, varscan2
- ZNF551 | c.1806C>T p.L602= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99990453; called by muse, mutect2
- TMEM183B | n.536C>T | RNA (SNP) | VAF 55/110 reads (50%) | catalogued as rs372354699; called by muse, mutect2, varscan2
